CCDI case PBCVCB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/335f3247-b580-40ce-bf39-ac810edabb36

Demographics
Sex at birth: female.

Biospecimens (2 samples)
- Sample 0E0KXS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample 0E0KY9: Tissue type: Normal; Specimen type: Peripheral Whole Blood. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
